Somatic mutation profile of tumor specimen TCGA-N7-A59B-01A (aliquot TCGA-N7-A59B-01A-11D-A28R-08) from TCGA case TCGA-N7-A59B, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 69.4 years (25,360 days).
Specimen TCGA-N7-A59B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 068e5453-bbdd-4adf-95c7-9fbaca4c3c82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N7-A59B-10A (Blood Derived Normal), aliquot TCGA-N7-A59B-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed384ab6-2141-4d38-bfbb-a04005caacf4

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.4498C>T p.R1500W | Missense Mutation (SNP) | VAF 99/107 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs45544633, CM045547, COSV62516913; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 109/148 reads (74%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519930, COSV55874291, COSV55888676, COSV55926774; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 27/31 reads (87%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASPM | c.6995G>T p.R2332L | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV54142558; called by muse, mutect2, varscan2
- COQ8A | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as rs762900727, COSV62023325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DROSHA | c.2552G>T p.G851V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60773181; called by muse, mutect2, varscan2
- FHOD3 | c.2027G>A p.R676Q (on ENST00000359247 / NM_001281739.3; = p.R693Q on NM_025135.5) | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs778589963, COSV99939978; called by muse, mutect2, varscan2
- GPR45 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 84/163 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs112504064; called by muse, mutect2, varscan2
- HTRA4 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV56760398; called by muse, mutect2, varscan2
- KCNH2 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769197005, COSV51126648; called by muse, mutect2, varscan2
- LILRB5 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 120/259 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs755997832, COSV60256644, COSV60259897; called by muse, mutect2, varscan2
- LRP3 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99472857; called by muse, mutect2, varscan2
- PHRF1 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99199361; called by muse, mutect2, varscan2
- SAFB2 | c.2043_2057del p.M682_R686del | In Frame Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs748161277; called by mutect2, varscan2
- TBXAS1 | c.1335G>A p.W445* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as rs780174620; called by muse, mutect2, varscan2
- UNC13B | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV65931372; called by muse, mutect2, varscan2
- USP1 | c.498T>A p.N166K | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs766905656; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1262C>A p.T421N | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs746564908; called by muse, mutect2, varscan2
- BTN3A3 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREB5 | c.463G>C p.G155R (on ENST00000357727 / NM_182898.4; = p.G148R on NM_004904.3) | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CREBRF | c.58C>G p.H20D | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DNMT3B | c.1067-2A>G p.X356_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- DZIP3 | c.2078C>A p.A693E | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDRF1 | c.650_652del p.G217del | In Frame Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3881G>A p.W1294* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- GPRASP1 | c.3311C>T p.P1104L | Missense Mutation (SNP) | VAF 101/199 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- LIG4 | c.2191A>G p.K731E | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM | c.3611C>T p.T1204I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OTOGL | c.2247G>A p.M749I (on ENST00000547103; = p.M740I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2
- PAK4 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGAM4 | c.205A>T p.T69S | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PNMA5 | c.167T>A p.F56Y | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ROCK2 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SLC15A3 | c.1292A>T p.E431V | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- SNRPC | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TNRC6C | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- UBA1 | c.725T>C p.F242S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- USP1 | c.569del p.P190Lfs*29 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by pindel, varscan2
- USP10 | c.716del p.A239Efs*72 | Frame Shift Del (DEL) | VAF 16/24 reads (67%) | called by mutect2, pindel, varscan2
- ZNF284 | c.1751T>G p.M584R | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- IQCN | c.1485C>G p.T495= | Silent (SNP) | VAF 106/168 reads (63%) | called by muse, mutect2, varscan2
- NPM1 | c.453T>A p.V151= | Silent (SNP) | VAF 40/108 reads (37%) | called by muse, mutect2, varscan2
- OR13C8 | c.15C>T p.N5= | Silent (SNP) | VAF 51/56 reads (91%) | catalogued as COSV58611435; called by muse, mutect2, varscan2
- RNF113B | c.444G>A p.R148= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- RS1 | c.540G>A p.S180= | Silent (SNP) | VAF 52/97 reads (54%) | catalogued as rs767660711, COSV101183723; called by muse, mutect2, varscan2
- SORCS3 | c.3327G>A p.Q1109= | Silent (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- THAP8 | c.786C>A p.A262= | Silent (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
- TTC27 | c.2013A>T p.L671= | Silent (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
- ZNF358 | c.1431A>G p.K477= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs756816223; called by muse, mutect2
- ZNF799 | c.1689A>G p.Q563= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs1327730688; called by muse, mutect2, varscan2
